Gene-level copy-number profile of specimen HCM-SANG-0543-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0543-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0543-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 49c684fb-3710-4a6e-908d-d17ac01feed4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0543-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/2770ddc0-ee1a-4ee8-81cf-2efa0f672a73

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 382; copy number 1: 1,077; copy number 2: 23,674; copy number 3: 26,411; copy number 4: 5,753; copy number 5: 1,431; copy number 6: 89; copy number 7: 79; copy number 8: 6; copy number 9: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 90 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:206,770,764–207,099,993, 12 genes, copy number 7–9 (within-gene range 3–9): IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB.
- chr2:85,394,753–85,437,029, 4 genes, copy number 7: CAPG, AC062037.3, SH2D6, Y_RNA.
- chr10:25,113,058–25,176,276, 2 genes, copy number 7 (within-gene range 5–7): LINC01516, GPR158-AS1.
- chr19:48,296,457–49,119,143, 70 genes, copy number 7 (broad region; genes not listed).
- chr20:53,799,823–53,875,557, 2 genes, copy number 7: AC006076.1, SUMO1P1.

Autosomal genes at a single copy (total copy number 1): 785. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
